Somatic mutation profile of tumor specimen MP2PRT-PARWEB-TMP1-A (aliquot MP2PRT-PARWEB-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARWEB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,121 days).
Specimen MP2PRT-PARWEB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93ef2f4c-9a9d-4741-bca3-aee0e07fbcb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWEB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWEB-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a3b5431-a314-4868-82a9-39ad84aecbdb

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 137/374 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 236/467 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs747836852, COSV65888191; called by muse, mutect2, varscan2
- ARHGAP22 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 40/810 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs776616854; called by muse, mutect2
- CILP2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 258/502 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs563378304; called by muse, mutect2, varscan2
- CLDN4 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs782291578; called by muse, mutect2, varscan2
- COL20A1 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 306/690 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762131004; called by muse, mutect2, varscan2
- ESPNL | c.2470C>T p.R824W | Missense Mutation (SNP) | VAF 283/590 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557397670; called by muse, mutect2
- GJA5 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 30/550 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54783424; called by muse, mutect2
- GSTZ1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 148/482 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs369022018; called by muse, varscan2
- LGI2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 42/552 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1156361531, COSV66123027; called by muse, mutect2
- MMP8 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs563802778; called by muse, varscan2
- MPDZ | c.2364+1G>A p.X788_splice | Splice Site (SNP) | VAF 119/248 reads (48%) | catalogued as rs767669471, COSV59941891; called by muse, mutect2, varscan2
- NMNAT3 | c.293+1G>T p.X98_splice (on ENST00000296202 / NM_001320512.1; = p.X61_splice on NM_178177.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 134/271 reads (49%) | catalogued as rs990475297; called by muse, mutect2, varscan2
- RYR3 | c.12089G>A p.R4030H (on ENST00000389232; = p.R4031H on NM_001036.6) | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66793804, COSV66802959; called by muse, mutect2, varscan2
- SLC27A6 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 69/193 reads (36%) | catalogued as rs768100853, COSV52485929; called by muse, mutect2, varscan2
- ST6GAL2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 252/514 reads (49%) | PolyPhen probably damaging (0.975); catalogued as rs1488876821, COSV64529285; called by muse, mutect2, varscan2
- ARID5B | c.326_336del p.L109Rfs*4 | Frame Shift Del (DEL) | VAF 95/452 reads (21%) | called by mutect2, pindel*, varscan2
- CFAP47 | c.2753C>T p.T918I | Missense Mutation (SNP) | VAF 122/605 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- H1-5 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 22/794 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- MUC5AC | c.1119C>G p.F373L | Missense Mutation (SNP) | VAF 183/413 reads (44%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- SCN3A | c.4583_4584del p.F1528* | Frame Shift Del (DEL) | VAF 124/338 reads (37%) | called by mutect2, pindel, varscan2
- TTC39B | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 157/359 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP90 | c.1626A>T p.Q542H | Missense Mutation (SNP) | VAF 125/314 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DEFB113 | c.189G>A p.A63= | Silent (SNP) | VAF 151/581 reads (26%) | catalogued as rs779312079, COSV100435452; called by muse, mutect2, varscan2
- GREB1 | c.5760C>T p.D1920= | Silent (SNP) | VAF 28/538 reads (5%) | catalogued as rs780513457, COSV52180533, COSV52191810; called by muse, mutect2
- IRX2 | c.750C>T p.C250= | Silent (SNP) | VAF 240/622 reads (39%) | called by muse, mutect2, varscan2
- MCC | c.423C>T p.P141= | Silent (SNP) | VAF 148/355 reads (42%) | catalogued as rs112464620; called by muse, mutect2, varscan2
- SLCO1C1 | c.2004T>C p.Y668= | Silent (SNP) | VAF 117/287 reads (41%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1122G>A | RNA (SNP) | VAF 177/678 reads (26%) | catalogued as rs759991147, COSV52834912; called by muse, mutect2, varscan2
